Surgical pathology report (de-identified scan), TCGA case TCGA-HV-A7OL, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site National Cancer Center Korea, specimen TCGA-HV-A7OL-01A (Primary Tumor).

[page 1 of 2]
ICD-O-3
Adenocarcinoma, duct NOS
8500/3
Site: Pancreatic head
C25.0
JW 9/26/13

CLINICAL DIAGNOSIS: Pancreatic cancer

Specimen : pancreas

GROSS:

Specimen status: Fresh

Operation: Pylorus preserving pancreaticoduodenectomy and cholecystectomy

Organs:

Small intestine (17.0 cm in length and 3.5 cm in greatest circumference)

Pancreas, partial (5.5 x 4.0 x 3.0 cm)

Gallbladder (10.0 cm in length, 3.5 cm in diameter, and 0.3 cm in thickness)

Lesions:

An ill-defined pale tan solid and firm mass (2.0 x 1.8 x 1.5 cm) in pancreatic head

Cut surface: Yellowish tan, firm and granular

Extent: Extension to peripancreatic soft tissue

Resection margins of bile duct, small intestine and pancreas: Free of tumor

Frozen diagnosis

FS1, Bile duct margin: No tumor present

FS2-3, Pancreatic resection margin: Tumor present

FS4, More resected pancreatic resection margin: No tumor present

Gross photo: Present

MICROSCOPIC:

Tumor type: Ductal adenocarcinoma

Tumor location: Pancreatic head

Histologic grade: Moderately differentiated

Tumor size: 2.0 x 1.8 x 1.5 cm

Extent: Peripancreatic soft tissue, and muscle and submucosa of small intestine

Lymphovascular invasion: Present

Perineural invasion: Present

Surgical margins: All surgical margins are free from tumor

Lymph node metastasis: Absent (0/19)

[page 2 of 2]
DIAGNOSIS:

Pancreas, head, pylorus preserving pancreaticoduodenectomy:

Ductal adenocarcinoma, moderately differentiated, infiltrating

Small intestine, duodenum, pylorus preserving pancreaticoduodenectomy:

Direct tumor extension from pancreas

Bile duct, pylorus preserving pancreaticoduodenectomy:

No tumor present

Gallbladder, pylorus preserving pancreaticoduodenectomy:

Chronic cholecystitis

Lymph node, pylorus preserving pancreaticoduodenectomy:

Lymph node, 7: No tumor present (0/1)

Lymph node, 8: No tumor present (0/5)

Lymph node, 12: No tumor present (0/4)

Lymph node, 13: No tumor present (0/3)

Lymph node, peripancreatic: No tumor present (0/6)

Suggestion :

Source: NCI Genomic Data Commons file 95ed236e-d80d-4e0b-beee-fb48bde32a53 (TCGA-HV-A7OL.ECB0A827-3335-497C-9A5C-352B2042CB98.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).